Surgical pathology report (de-identified scan), TCGA case TCGA-16-1055, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Toronto Western Hospital, specimen TCGA-16-1055-01B (Primary Tumor).

16-1055

Patient Name: [REDACTED]

MRN: [REDACTED]

Gender: M

HCN: [REDACTED]

Ordering MD: [REDACTED]

Service: Surgical Service

Visit #: [REDACTED]

Location: [REDACTED]

Facility: [REDACTED]

Copath #: [REDACTED]

Collected: [REDACTED]

Resulted: [REDACTED]

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. BRN: left frontal brain tumor [REDACTED]
2. BRN: left frontal brain tumor

DIAGNOSIS

Glioblastoma Multiforme (Malignant Astrocytoma- WHO Grade IV)- (Left Frontal Lobe)

GROSS DESCRIPTION

1. The specimen container, labeled with the patient's name and as "left frontal brain tumor qs", contains one fragment of tan-colored hemorrhagic tissue received fresh measuring in aggregate 0.7 x 0.2 x 0.1 cm. The specimen is submitted in toto as follows:
1A - frozen section resubmitted.

2. The specimen container, labeled with the patient's name and as "left frontal brain tumor", contains a piece of red-tan tissue, received in 10% [REDACTED]. This measures 2.4 x 2.8 x 1.2 cm and weighs 4 grams.
2A and 2B - serially sectioned and submitted in toto

QUICK SECTION

- 1A "Malignant astrocytoma".

MICROSCOPIC DESCRIPTION

This tumor displays all the usual features of glioblastoma multiforme.

Source: NCI Genomic Data Commons file 3adf1d43-d9bf-49f8-ace4-5ff51b001bf3 (TCGA-16-1055.E7113657-7A5B-42B2-9489-E0C414513FF8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).